Somatic mutation profile of tumor specimen MP2PRT-PAUDLB-TMP1-A (aliquot MP2PRT-PAUDLB-TMP1-A-1-0-D-A83P-36) from MP2PRT case MP2PRT-PAUDLB, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 6.5 years (2,376 days).
Specimen MP2PRT-PAUDLB-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) dbaac13f-b98c-487e-ad3b-ca80d2249289.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAUDLB-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAUDLB-NB1-A-1-0-D-A83P-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d91dd495-27d8-4a94-821c-17be3ba08fb3

The open-access MAF lists 39 somatic variants for this specimen: 29 protein-altering or splice-affecting, 9 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 28, Silent 9, 5'Flank 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PTPN11 | c.227A>G p.E76G | Missense Mutation (SNP) | VAF 81/571 reads (14%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen possibly damaging (0.813); catalogued as rs121918465, CM112765, CM1314032, CM137734, COSV61005372, COSV61006382, COSV61007426; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ABCD1 | c.31C>G p.R11G | Missense Mutation (SNP) | VAF 46/702 reads (7%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.095); catalogued as rs1224689084; called by muse, mutect2
- BRD7 | c.1594G>A p.E532K | Missense Mutation (SNP) | VAF 16/299 reads (5%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.643); catalogued as rs761156191; called by muse, mutect2
- CHRNA2 | c.169G>A p.E57K | Missense Mutation (SNP) | VAF 32/617 reads (5%) | SIFT tolerated (0.37); PolyPhen benign (0.001); catalogued as rs139552324; ClinVar: uncertain significance; called by muse, mutect2
- COL6A3 | c.4678G>A p.A1560T | Missense Mutation (SNP) | VAF 247/545 reads (45%) | SIFT deleterious (0.04); PolyPhen benign (0.298); catalogued as rs371631320; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CSMD1 | c.9496C>G p.R3166G (on ENST00000520002; = p.R3165G on NM_033225.6) | Missense Mutation (SNP) | VAF 166/366 reads (45%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.928); catalogued as COSV59293387, COSV59386731; called by muse, mutect2, varscan2
- FAM180A | c.407G>A p.R136H | Missense Mutation (SNP) | VAF 52/611 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.953); catalogued as rs777605103; called by muse, mutect2
- FAM53A | c.821G>A p.R274Q | Missense Mutation (SNP) | VAF 84/586 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs755904567; called by muse, mutect2, varscan2
- FOXM1 | c.706C>T p.R236W | Missense Mutation (SNP) | VAF 33/546 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs760175330; called by muse, mutect2
- GPC6 | c.1342G>A p.E448K | Missense Mutation (SNP) | VAF 157/395 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs748920798; called by muse, mutect2, varscan2
- GPR158 | c.46C>T p.Q16* | Nonsense Mutation (SNP) | VAF 181/406 reads (45%) | catalogued as COSV100894207, COSV66275892; called by muse, mutect2, varscan2
- HTR4 | c.409C>T p.R137C | Missense Mutation (SNP) | VAF 144/420 reads (34%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.998); catalogued as rs186099216, COSV58806831; called by muse, varscan2
- INSL4 | c.187C>T p.R63C | Missense Mutation (SNP) | VAF 39/252 reads (15%) | SIFT tolerated (0.07); PolyPhen benign (0.069); catalogued as rs188521238, COSV53329748; called by muse, mutect2, varscan2
- MROH2B | c.3155C>A p.T1052K | Missense Mutation (SNP) | VAF 124/345 reads (36%) | SIFT deleterious (0.05); PolyPhen benign (0.031); catalogued as rs993601040, COSV101270590; called by muse, mutect2, varscan2
- PHF8 | c.2441G>A p.R814Q (on ENST00000357988 / NM_001184896.1; = p.R778Q on NM_015107.3) | Missense Mutation (SNP) | VAF 12/396 reads (3%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.988); catalogued as rs782762274; called by muse, mutect2
- SDR42E1 | c.842G>A p.R281H | Missense Mutation (SNP) | VAF 209/537 reads (39%) | SIFT tolerated (0.2); PolyPhen benign (0.023); catalogued as rs370136905; called by muse, mutect2, varscan2
- TTN | c.26534C>T p.T8845M (on ENST00000591111; = p.T7918M on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 42/573 reads (7%) | PolyPhen possibly damaging (0.819); catalogued as rs199793620; ClinVar: uncertain significance / likely benign / conflicting interpretations of pathogenicity; called by muse, mutect2
- CCDC105 | c.310G>A p.A104T | Missense Mutation (SNP) | VAF 38/1028 reads (4%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.892); called by muse, mutect2
- CERS6 | c.1133G>A p.G378D | Missense Mutation (SNP) | VAF 55/377 reads (15%) | SIFT tolerated (0.06); PolyPhen benign (0.348); called by muse, mutect2, varscan2
- CRB2 | c.2941G>A p.A981T | Missense Mutation (SNP) | VAF 32/801 reads (4%) | SIFT tolerated (0.39); PolyPhen benign (0.006); called by muse, mutect2
- GPR158 | c.47A>T p.Q16L | Missense Mutation (SNP) | VAF 181/406 reads (45%) | SIFT tolerated, low confidence (0.83); PolyPhen benign (0); called by muse, mutect2, varscan2
- MEIOC | c.1655G>T p.G552V | Missense Mutation (SNP) | VAF 35/400 reads (9%) | SIFT deleterious (0.04); PolyPhen benign (0.436); called by muse, mutect2
- PABPC4 | c.776A>C p.K259T | Missense Mutation (SNP) | VAF 57/418 reads (14%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.457); called by muse, mutect2, varscan2
- PDZRN4 | c.3095C>T p.S1032L (on ENST00000402685 / NM_001164595.2; = p.S774L on NM_013377.4) | Missense Mutation (SNP) | VAF 116/251 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); called by muse, mutect2, varscan2
- POP5 | c.281A>G p.Y94C | Missense Mutation (SNP) | VAF 58/402 reads (14%) | SIFT tolerated (0.11); PolyPhen benign (0.117); called by muse, varscan2
- SIX2 | c.740G>A p.G247D | Missense Mutation (SNP) | VAF 32/868 reads (4%) | SIFT deleterious (0); PolyPhen benign (0); called by muse, mutect2
- SLCO6A1 | c.575C>T p.S192F | Missense Mutation (SNP) | VAF 81/260 reads (31%) | SIFT tolerated (0.16); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- TUBG2 | c.95G>A p.S32N | Missense Mutation (SNP) | VAF 44/658 reads (7%) | SIFT tolerated (0.39); PolyPhen benign (0.001); called by muse, mutect2
- URB2 | c.442G>A p.A148T | Missense Mutation (SNP) | VAF 29/603 reads (5%) | SIFT tolerated (0.32); PolyPhen benign (0.001); called by muse, mutect2
- C10orf120 | c.576C>G p.S192= | Silent (SNP) | VAF 214/609 reads (35%) | called by muse, mutect2, varscan2
- MEIS2 | c.396C>T p.A132= (on ENST00000561208 / NM_170675.5; = p.A119= on NM_002399.3) | Silent (SNP) | VAF 16/383 reads (4%) | catalogued as rs1286820299; called by muse, mutect2
- MGAT3 | c.867C>T p.D289= | Silent (SNP) | VAF 196/518 reads (38%) | catalogued as rs144639692, COSV100361830; called by muse, varscan2
- MYCBPAP | c.1423C>A p.R475= | Silent (SNP) | VAF 16/342 reads (5%) | catalogued as COSV60409236; called by muse, mutect2
- OR2G2 | c.678C>T p.H226= | Silent (SNP) | VAF 47/302 reads (16%) | catalogued as rs779772045, COSV60740879; called by muse, mutect2, varscan2
- OR5D3P | c.576C>A p.A192= | Silent (SNP) | VAF 115/329 reads (35%) | called by muse, mutect2, varscan2
- OTUD7B | c.2226C>T p.H742= | Silent (SNP) | VAF 27/545 reads (5%) | called by muse, mutect2
- SLCO6A1 | c.576C>T p.S192= | Silent (SNP) | VAF 81/258 reads (31%) | catalogued as rs375167880; called by muse, mutect2, varscan2
- UGT1A7 | c.486C>A p.S162= | Silent (SNP) | VAF 22/386 reads (6%) | called by muse, mutect2
- ARIH2 | chr3:48918595 C>G | 5'Flank (SNP) | VAF 20/544 reads (4%) | called by muse, mutect2
